Gene-level copy-number profile of tumor specimen TCGA-64-5775-01A from TCGA case TCGA-64-5775, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.3 years (26,058 days).
Specimen TCGA-64-5775-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.872a33bc-abe3-458a-862f-273905e20f38.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-64-5775-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/968bea8a-e45b-4667-afc3-045d32d6d1ce

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 8,584; copy number 3: 35,437; copy number 4: 9,371; copy number 5: 2,637; copy number 6: 2,400; copy number 7: 1,100; copy number 8: 95; copy number 9: 9; copy number 10: 109; copy number 12: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-64-5775-01A-01D-1624-01): tumor purity 0.71, ploidy 3.39, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,386 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,228,682–64,181,498, 98 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:65,248,219–65,415,871, 1 gene, copy number 10 (within-gene range 4–10): DNAJC6.
- chr1:65,415,816–80,646,791, 205 genes, copy number 7–12 (broad region; genes not listed).
- chr1:83,575,776–88,891,944, 87 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr6:62,547,427–66,094,909, 29 genes, copy number 7: AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1.
- chr8:39,903,775–39,995,248, 1 gene, copy number 9 (within-gene range 5–9): AC007991.3.
- chr8:39,934,614–40,402,010, 8 genes, copy number 9 (within-gene range 5–9): IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1.
- chr12:66,767–44,503,596, 941 genes, copy number 7–8 (broad region; genes not listed).
- chr18:6,256,747–6,601,836, 9 genes, copy number 7: L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P.
- chr18:6,729,716–6,937,020, 6 genes, copy number 7 (within-gene range 4–7): ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P.
- chr18:6,954,677–6,957,419, 1 gene, copy number 7: AP002409.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
